Somatic mutation profile of tumor specimen CPT008916 (aliquot CPT008916-0002) from CPTAC case 01BR010, project CPTAC-2 (Breast). Tissue or organ of origin: Breast, NOS.
Specimen CPT008916: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3cc5280-bd77-4660-9711-1e0b62bfb221.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT008526 (Blood Derived Normal), aliquot CPT008526-0001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9776b348-52d3-4fe7-83cb-ce44455a62d5

The open-access MAF lists 52 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 8, Intron 5, Nonsense Mutation 3, 5'UTR 2, 5'Flank 2, Splice Region 1, 3'UTR 1, In Frame Del 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.337_339del p.L113del | In Frame Del (DEL) | VAF 26/100 reads (26%) | hotspot (GDC flag); called by mutect2, pindel
- CCDC168 | c.17515C>T p.R5839W | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs768351446, COSV59419863; called by muse, mutect2, varscan2
- CUX2 | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99920000; called by muse, mutect2
- DCTN1 | c.1260G>C p.E420D | Missense Mutation (SNP) | VAF 30/449 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs751393307; called by muse, mutect2
- H4C5 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV63487275; called by muse, mutect2
- MTHFR | c.1319C>A p.S440* | Nonsense Mutation (SNP) | VAF 56/431 reads (13%) | catalogued as CM035840; called by muse, mutect2, varscan2
- PCDHA6 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 182/982 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65345659; called by mutect2, varscan2
- PKD1 | c.4427C>G p.S1476C | Missense Mutation (SNP) | VAF 77/635 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs563980883; called by muse, mutect2, varscan2
- RIMKLA | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257985060, COSV101290545, COSV68909828; called by muse, mutect2
- SLC16A11 | c.476C>G p.S159C (on ENST00000308009; = p.S135C on NM_153357.3) | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV57274482; called by muse, mutect2, varscan2
- SSH1 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs781444832, COSV58454351; called by muse, mutect2, varscan2
- TPH1 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 63/528 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1198363678; called by muse, mutect2, varscan2
- VPS28 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1378342216; called by muse, mutect2, varscan2
- CDH23 | c.8789T>C p.V2930A | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2
- CDK15 | c.792G>T p.W264C (on ENST00000652192 / NM_001366386.2; = p.W213C on NM_139158.2) | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- EXOSC10 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 27/166 reads (16%) | called by muse, mutect2, varscan2
- FLT3 | c.974C>G p.T325S | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IER2 | c.565A>T p.S189C | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- INTS6 | c.1642C>G p.P548A | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- IWS1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.227); called by muse, mutect2
- LENG9 | c.313del p.C105Afs*133 | Frame Shift Del (DEL) | VAF 28/167 reads (17%) | called by mutect2, pindel, varscan2
- LZTR1 | c.104C>G p.S35W | Missense Mutation (SNP) | VAF 105/398 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYOM3 | c.3768C>T p.H1256= | Splice Region (SNP) | VAF 26/227 reads (11%) | called by muse, mutect2, varscan2
- NOA1 | c.132C>G p.H44Q | Missense Mutation (SNP) | VAF 40/454 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- OR10A5 | c.761T>A p.I254K | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PRKDC | c.5762A>T p.D1921V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SENP7 | c.538A>C p.I180L | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- SLC25A38 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 112/532 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TJP1 | c.1267A>T p.K423* | Nonsense Mutation (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- TMEM208 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TNFSF11 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 41/495 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- VWA3A | c.3508C>G p.Q1170E | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.525); called by muse, mutect2
- WASF3 | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCL25 | c.222G>T p.V74= | Silent (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2
- CCT3 | c.1182C>A p.A394= | Silent (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- DDX31 | c.933C>T p.L311= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as rs757216752; called by muse, mutect2, varscan2
- MAGEL2 | c.534G>A p.P178= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as rs532688869; called by muse, mutect2, varscan2
- MPP6 | c.1123C>A p.R375= | Silent (SNP) | VAF 24/238 reads (10%) | called by muse, mutect2, varscan2
- PEX26 | c.703T>C p.L235= | Silent (SNP) | VAF 86/764 reads (11%) | catalogued as rs1425394912; called by mutect2, varscan2
- SYNPO2 | c.483C>A p.G161= | Silent (SNP) | VAF 40/176 reads (23%) | called by muse, mutect2, varscan2
- TERB1 | c.561C>A p.V187= | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- ABCB8 | c.95+215T>A | Intron (SNP) | VAF 38/191 reads (20%) | called by muse, mutect2, varscan2
- BSCL2 | chr11:62709494 T>C | 5'Flank (SNP) | VAF 16/120 reads (13%) | catalogued as rs966312833; called by muse, mutect2, varscan2
- DCAF17 | c.*1260A>G | 3'UTR (SNP) | VAF 38/198 reads (19%) | called by mutect2, varscan2
- NIPAL1 | c.-59T>A | 5'UTR (SNP) | VAF 34/284 reads (12%) | called by muse, mutect2, varscan2
- NTRK1 | c.1178-39C>T | Intron (SNP) | VAF 44/342 reads (13%) | called by muse, mutect2, varscan2
- OR56B3P | n.821C>A | RNA (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2
- SREBF1 | c.2384-15T>A | Intron (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2
- TTLL9 | c.70-7353C>A | Intron (SNP) | VAF 10/80 reads (13%) | catalogued as rs943453413; called by muse, mutect2, varscan2
- TUBA1A | c.226+20C>A | Intron (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- USP15 | chr12:62260379 C>A | 5'Flank (SNP) | VAF 32/296 reads (11%) | called by muse, mutect2, varscan2
- ZNF19 | c.-9G>A | 5'UTR (SNP) | VAF 48/262 reads (18%) | called by muse, mutect2, varscan2
